CCDI case PBBTZC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b82598ae-b8f4-4a0f-8838-737e187c1758

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 5.9 years (2,166 days).

Biospecimens (3 samples)
- Sample 0DGWOA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGWOD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGWOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
